HCMI case HCM-SANG-0779-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/74512b64-70e7-4d12-b9b8-8810d7a3bf34

Demographics
Sex at birth: female; Days to birth: -22,828 days (62.5 years before the index date).

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreatic duct; Classification of tumor: primary; Prior malignancy: no; Uicc clinical stage: Stage III; Uicc pathologic n: N0; Uicc pathologic t: T4; Uicc staging system edition: 7th.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 28.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 133 days.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Pancreatitis.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-SANG-0779-C25-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-0779-C25-85A-01D-A80T-32, HCM-SANG-0779-C25-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
